Somatic mutation profile of tumor specimen TCGA-EL-A3MW-01A (aliquot TCGA-EL-A3MW-01A-11D-A20C-08) from TCGA case TCGA-EL-A3MW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 55.3 years (20,186 days).
Specimen TCGA-EL-A3MW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4929b6bc-43a7-4d56-a16c-da0a0fd62e7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3MW-11A (Solid Tissue Normal), aliquot TCGA-EL-A3MW-11A-11D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f163e2-d258-4c66-a874-202f8b0f13ac

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC42 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV53449818; called by muse, mutect2
- DCC | c.2251C>A p.P751T | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as COSV59133708; called by muse, mutect2
- KSR2 | c.2012T>A p.L671H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV56682943, COSV56684819; called by muse, mutect2
- PGM2 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV67939529; called by muse, mutect2, varscan2
- TMEM63B | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52482334; called by muse, mutect2, varscan2
- ZCWPW1 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV61250531; called by muse, mutect2
- GAA | c.687C>T p.R229= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs149814041; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
